Somatic mutation profile of tumor specimen TCGA-43-3394-01A (aliquot TCGA-43-3394-01A-01D-0983-08) from TCGA case TCGA-43-3394, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 52.9 years (19,310 days).
Specimen TCGA-43-3394-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e048497c-0b14-4d4d-a71b-eb03541904a6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-43-3394-10A (Blood Derived Normal), aliquot TCGA-43-3394-10A-01D-0983-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a1a75517-993a-488b-8f90-271af9652057

The open-access MAF lists 150 somatic variants for this specimen: 116 protein-altering or splice-affecting, 32 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 92, Silent 32, Nonsense Mutation 10, Frame Shift Del 5, Frame Shift Ins 4, Splice Site 4, Splice Region 1, RNA 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA13 | c.3176A>G p.H1059R | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.88); catalogued as COSV70031360; called by muse, mutect2, varscan2
- ADAM10 | c.1931G>A p.R644Q | Missense Mutation (SNP) | VAF 29/77 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.021); catalogued as rs779647116, COSV53052019; called by muse, mutect2, varscan2
- ADAMTS20 | c.3316G>T p.E1106* | Nonsense Mutation (SNP) | VAF 76/116 reads (66%) | catalogued as COSV67132959; called by muse, mutect2, varscan2
- ADGRE2 | c.269G>A p.G90E | Missense Mutation (SNP) | VAF 31/84 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV59694037; called by muse, mutect2, varscan2
- ADGRE2 | c.122A>T p.N41I | Missense Mutation (SNP) | VAF 18/98 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as COSV59694045; called by muse, varscan2
- AHNAK | c.727A>T p.K243* | Nonsense Mutation (SNP) | VAF 14/69 reads (20%) | catalogued as COSV57216159; called by muse, mutect2, varscan2
- ANKRD34B | c.1213T>C p.S405P | Missense Mutation (SNP) | VAF 27/41 reads (66%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as rs1451843804, COSV58614020; called by muse, mutect2, varscan2
- ANPEP | c.1176C>A p.H392Q | Missense Mutation (SNP) | VAF 46/99 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748152165, COSV55592084; called by muse, mutect2, varscan2
- APC | c.2896A>G p.S966G | Missense Mutation (SNP) | VAF 16/28 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV57349827, COSV57397870; called by muse, mutect2, varscan2
- ARID1A | c.5532G>A p.W1844* | Nonsense Mutation (SNP) | VAF 42/63 reads (67%) | catalogued as COSV61379288; called by muse, mutect2, varscan2
- ASPM | c.8601G>T p.Q2867H | Missense Mutation (SNP) | VAF 20/29 reads (69%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.99); catalogued as COSV54131136; called by muse, mutect2, varscan2
- ATAD2 | c.3792G>C p.L1264F | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.4); PolyPhen benign (0.078); catalogued as COSV54881638, COSV54882981; called by muse, mutect2, varscan2
- ATP8A1 | c.3037G>T p.G1013W | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52536939; called by muse, mutect2, varscan2
- C5orf38 | c.212C>G p.S71* | Nonsense Mutation (SNP) | VAF 70/153 reads (46%) | catalogued as rs1041567068, COSV57411635; called by muse, mutect2, varscan2
- CANX | c.1729G>T p.D577Y | Missense Mutation (SNP) | VAF 14/21 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV52986124; called by muse, mutect2, varscan2
- CBLL1 | c.1273A>G p.N425D | Missense Mutation (SNP) | VAF 54/177 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.418); catalogued as COSV56029142; called by muse, mutect2, varscan2
- CCDC189 | c.428C>A p.A143E | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.483); catalogued as COSV60312338; called by muse, mutect2, varscan2
- CCR3 | c.701dup p.Y235Vfs*38 | Frame Shift Ins (INS) | VAF 22/40 reads (55%) | catalogued as rs761073142; called by mutect2, varscan2
- CERK | c.1459C>A p.H487N | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as COSV53451739; called by muse, mutect2, varscan2
- CFAP251 | c.2911G>A p.D971N | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.091); catalogued as rs1318095723, COSV56611223, COSV56612298; called by mutect2, varscan2
- CHD5 | c.5506G>A p.A1836T | Missense Mutation (SNP) | VAF 30/49 reads (61%) | SIFT deleterious (0.01); PolyPhen benign (0.407); catalogued as COSV52416414; called by muse, mutect2, varscan2
- CIITA | c.2357A>T p.Q786L | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.673); catalogued as COSV100162333; called by muse, mutect2, varscan2
- CLEC17A | c.1019A>G p.E340G (on ENST00000417570 / NM_001204118.2; = p.R303= on NM_207390.3) | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT tolerated (0.66); PolyPhen benign (0.019); catalogued as COSV60428146; called by muse, mutect2, varscan2
- CLSTN2 | c.2113G>T p.D705Y | Missense Mutation (SNP) | VAF 28/101 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); catalogued as COSV71721332; called by muse, mutect2, varscan2
- CNGA2 | c.842A>G p.Y281C | Missense Mutation (SNP) | VAF 51/77 reads (66%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV61704926; called by muse, mutect2, varscan2
- COL1A1 | c.2829+2T>C p.X943_splice | Splice Site (SNP) | VAF 19/64 reads (30%) | catalogued as COSV56805972; called by muse, mutect2, varscan2
- CRACDL | c.187G>A p.V63I | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.543); catalogued as COSV67408496; called by mutect2, varscan2
- CRYBG1 | c.2036C>A p.T679N | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT tolerated (0.91); PolyPhen benign (0.045); catalogued as COSV64812536; called by mutect2, varscan2
- CSAD | c.496C>T p.Q166* (on ENST00000444623 / NM_001244705.2; = p.Q193* on NM_015989.5) | Nonsense Mutation (SNP) | VAF 23/44 reads (52%) | catalogued as COSV57241165; called by muse, mutect2, varscan2
- CT83 | c.67C>T p.R23C | Missense Mutation (SNP) | VAF 55/84 reads (65%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.942); catalogued as COSV64141109; called by muse, mutect2, varscan2
- CTTNBP2NL | c.941C>A p.T314K | Missense Mutation (SNP) | VAF 33/138 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV54744971; called by muse, mutect2, varscan2
- DCP1B | c.1795A>G p.I599V | Missense Mutation (SNP) | VAF 36/44 reads (82%) | SIFT tolerated (0.08); PolyPhen benign (0.437); catalogued as COSV54969709; called by muse, mutect2, varscan2
- EBF1 | c.383T>C p.V128A | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.882); catalogued as COSV58181174; called by muse, mutect2, varscan2
- ERI3 | c.241G>T p.A81S | Missense Mutation (SNP) | VAF 65/126 reads (52%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.331); catalogued as COSV64831955; called by muse, mutect2, varscan2
- ETV6 | c.542G>T p.R181L | Missense Mutation (SNP) | VAF 56/388 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.218); catalogued as CM156387, COSV67150627; called by muse, mutect2, varscan2
- FAT1 | c.5941C>T p.Q1981* | Nonsense Mutation (SNP) | VAF 82/150 reads (55%) | catalogued as COSV71674595; called by muse, mutect2, varscan2
- FILIP1L | c.2704C>T p.L902F (on ENST00000354552 / NM_182909.3; = p.L662F on NM_014890.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 98/197 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs755959064, COSV58769950; called by muse, mutect2, varscan2
- FREM1 | c.2273G>A p.G758D | Missense Mutation (SNP) | VAF 57/93 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs762884235, COSV66524887; called by muse, mutect2, varscan2
- GDPD5 | c.657G>T p.M219I | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (0.15); PolyPhen benign (0.135); catalogued as COSV61128230; called by muse, mutect2, varscan2
- GOLGA3 | c.70C>A p.P24T | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.085); catalogued as COSV52633514; called by muse, mutect2, varscan2
- GRM2 | c.1109T>C p.V370A | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT tolerated (0.63); PolyPhen benign (0.001); catalogued as COSV56585366; called by muse, mutect2, varscan2
- HBP1 | c.1007C>T p.P336L | Missense Mutation (SNP) | VAF 75/181 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56017968; called by muse, mutect2, varscan2
- HDAC9 | c.1757C>T p.S586F | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.133); catalogued as COSV67768027, COSV67774984; called by muse, mutect2
- HS6ST1 | c.612G>T p.W204C | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1476524169, COSV52128583; called by muse, mutect2, varscan2
- ICA1 | c.598C>A p.L200I | Missense Mutation (SNP) | VAF 30/64 reads (47%) | SIFT tolerated (0.18); PolyPhen benign (0.422); catalogued as COSV55579888; called by muse, varscan2
- IFT80 | c.2005A>C p.S669R | Missense Mutation (SNP) | VAF 51/136 reads (38%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as COSV58446778, COSV58448392; called by muse, mutect2, varscan2
- IL9R | c.801G>C p.W267C | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.517); catalogued as COSV54900287; called by muse, mutect2, varscan2
- IMPG1 | c.338T>C p.F113S | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64058687; called by muse, mutect2, varscan2
- INHBA | c.343G>C p.E115Q | Missense Mutation (SNP) | VAF 22/340 reads (6%) | SIFT tolerated (0.19); PolyPhen benign (0.1); catalogued as COSV54222110; called by muse, mutect2
- KMT2D | c.9260G>T p.R3087L | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.018); catalogued as COSV56408850, COSV56449418; called by muse, mutect2, varscan2
- LAMB4 | c.158G>C p.R53T | Missense Mutation (SNP) | VAF 38/108 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.085); catalogued as COSV52721124; called by muse, mutect2, varscan2
- LCN6 | c.228C>A p.H76Q | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV57910681; called by muse, mutect2, varscan2
- MAGEL2 | c.3745C>A p.R1249S | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.014); catalogued as rs769676927, COSV58566066, COSV58567423, COSV58567519; called by muse, mutect2, varscan2
- MBD5 | c.2749A>G p.S917G | Missense Mutation (SNP) | VAF 61/153 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.037); catalogued as COSV68697413; called by muse, mutect2, varscan2
- MCF2 | c.811C>A p.L271I | Missense Mutation (SNP) | VAF 66/99 reads (67%) | SIFT tolerated (0.37); PolyPhen benign (0.186); catalogued as COSV58486759; called by muse, mutect2, varscan2
- MDN1 | c.6047A>T p.Y2016F | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated (0.45); PolyPhen benign (0.017); catalogued as COSV65519537, COSV65522964; called by muse, mutect2, varscan2
- MROH2B | c.4699G>T p.A1567S | Missense Mutation (SNP) | VAF 94/397 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.796); catalogued as COSV68185076; called by muse, mutect2, varscan2
- MSI1 | c.271G>A p.D91N | Missense Mutation (SNP) | VAF 34/124 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57456642; called by muse, mutect2, varscan2
- NF1 | c.5201A>T p.E1734V (on ENST00000358273 / NM_001042492.3; = p.E1713V on NM_000267.3) | Missense Mutation (SNP) | VAF 39/90 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.322); catalogued as COSV55986128; called by muse, mutect2, varscan2
- NID2 | c.4061C>T p.P1354L | Missense Mutation (SNP) | VAF 23/44 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1447967658, COSV53497513; called by muse, mutect2, varscan2
- NPY1R | c.485T>G p.I162S | Missense Mutation (SNP) | VAF 30/50 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as COSV56714874; called by muse, mutect2, varscan2
- NRXN3 | c.2359A>T p.S787C (on ENST00000335750 / NM_001330195.2; = p.S414C on NM_004796.6) | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.11); catalogued as COSV59758315, COSV59768534; called by muse, mutect2, varscan2
- NXPE4 | c.59C>A p.S20Y | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.054); catalogued as rs754109857, COSV64943890; called by muse, mutect2, varscan2
- OCRL | c.2470-1G>T p.X824_splice | Splice Site (SNP) | VAF 34/47 reads (72%) | catalogued as COSV63981057; called by mutect2, varscan2
- OR4D5 | c.376A>G p.I126V | Missense Mutation (SNP) | VAF 31/75 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.893); catalogued as COSV58307442; called by muse, mutect2, varscan2
- OR52E6 | c.298C>A p.L100I | Missense Mutation (SNP) | VAF 29/154 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.05); catalogued as COSV61432313; called by muse, mutect2, varscan2
- OR6C6 | c.292C>A p.Q98K | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.506); catalogued as COSV64455847; called by muse, mutect2, varscan2
- OSER1 | c.780C>G p.F260L | Missense Mutation (SNP) | VAF 26/47 reads (55%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as COSV54853884; called by muse, mutect2, varscan2
- OTOGL | c.458G>T p.C153F (on ENST00000547103; = p.C144F on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV101509421; called by muse, mutect2, varscan2
- PCNT | c.110A>G p.K37R | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.965); catalogued as COSV52450080; called by muse, mutect2, varscan2
- PCNX3 | c.5156G>A p.R1719Q | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.625); catalogued as rs771900681, COSV63137406; called by muse, mutect2, varscan2
- PCTP | c.452G>T p.R151L | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs762655094, COSV52122821; called by muse, mutect2, varscan2
- PEPD | c.769G>T p.G257* | Nonsense Mutation (SNP) | VAF 10/26 reads (38%) | catalogued as rs755947485, COSV54891280, COSV54896287; called by muse, mutect2, varscan2
- PIK3AP1 | c.1525G>A p.E509K | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT tolerated (0.5); PolyPhen benign (0.022); catalogued as COSV59533386; called by muse, mutect2, varscan2
- PIP4K2C | c.769G>A p.E257K | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT tolerated (0.1); PolyPhen benign (0.3); catalogued as rs370140414; called by muse, mutect2, varscan2
- PLCG2 | c.2062G>T p.G688C | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV63867628; called by muse, mutect2, varscan2
- PLCG2 | c.2063G>T p.G688V | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV63867799, COSV63870666; called by muse, mutect2, varscan2
- PRSS37 | c.567+2T>A p.X189_splice | Splice Site (SNP) | VAF 30/71 reads (42%) | catalogued as COSV100633883, COSV63339531; called by muse, mutect2, varscan2
- RBL1 | c.1808G>C p.G603A | Missense Mutation (SNP) | VAF 36/62 reads (58%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV60330418; called by muse, mutect2, varscan2
- RFX4 | c.1994G>T p.R665I (on ENST00000392842 / NM_213594.3; = p.R571I on NM_032491.6) | Missense Mutation (SNP) | VAF 46/157 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.011); catalogued as COSV57576544; called by muse, mutect2, varscan2
- RNF144A | c.112T>C p.C38R | Missense Mutation (SNP) | VAF 29/88 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV57982973; called by muse, mutect2, varscan2
- RNF213 | c.52T>G p.C18G | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as COSV100173709; called by muse, mutect2, varscan2
- RNMT | c.1271A>G p.N424S | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (0.47); PolyPhen benign (0.011); catalogued as COSV51085679; called by mutect2, varscan2
- RXRA | c.521A>T p.N174I | Missense Mutation (SNP) | VAF 23/84 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.082); catalogued as COSV62684432; called by muse, mutect2, varscan2
- SATL1 | c.965C>G p.P322R (on ENST00000395409; = p.P509R on NM_001012980.2) | Missense Mutation (SNP) | VAF 26/39 reads (67%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.942); catalogued as COSV60576983; called by muse, mutect2, varscan2
- SECISBP2L | c.1841del p.P614Hfs*12 (on ENST00000559471 / NM_001193489.2; = p.P569Hfs*12 on NM_014701.4) | Frame Shift Del (DEL) | VAF 11/51 reads (22%) | catalogued as COSV99960136; called by mutect2, pindel, varscan2
- SEMA3D | c.376A>T p.T126S | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.25); PolyPhen benign (0.207); catalogued as COSV52395339; called by muse, mutect2, varscan2
- SLC27A6 | c.628C>G p.H210D | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.348); catalogued as COSV52483948, COSV52485806; called by muse, mutect2, varscan2
- SLC9A9 | c.554T>C p.V185A | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as COSV57230352; called by muse, mutect2, varscan2
- SLIT2 | c.3321T>C p.S1107= | Splice Region (SNP) | VAF 18/29 reads (62%) | catalogued as COSV56575552; called by muse, mutect2, varscan2
- SLITRK4 | c.280A>T p.K94* | Nonsense Mutation (SNP) | VAF 35/55 reads (64%) | catalogued as COSV62024309; called by muse, mutect2, varscan2
- SYN1 | c.724G>A p.E242K | Missense Mutation (SNP) | VAF 13/16 reads (81%) | SIFT deleterious (0.04); PolyPhen benign (0.25); catalogued as COSV55982221; called by muse, mutect2, varscan2
- TENM3 | c.3502G>C p.D1168H | Missense Mutation (SNP) | VAF 25/42 reads (60%) | SIFT tolerated (0.14); PolyPhen benign (0.445); catalogued as COSV69310293; called by muse, mutect2, varscan2
- TEX13A | c.352C>A p.Q118K | Missense Mutation (SNP) | VAF 12/18 reads (67%) | SIFT tolerated (0.25); PolyPhen benign (0.02); catalogued as COSV61161589; called by muse, mutect2, varscan2
- THSD7B | c.2272G>A p.A758T | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated (0.29); PolyPhen benign (0.009); catalogued as COSV55695825; called by muse, mutect2, varscan2
- TMEM52B | c.136T>C p.W46R (on ENST00000381923 / NM_001079815.1; = p.W26R on NM_153022.4) | Missense Mutation (SNP) | VAF 17/105 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs780856456, COSV53728607; called by muse, mutect2, varscan2
- TNRC6A | c.1358C>A p.P453Q | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59365187, COSV59371514; called by muse, mutect2, varscan2
- TNXB | c.5110G>A p.V1704M (on ENST00000647633; = p.V1457M on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.173); catalogued as rs201153451; called by muse, mutect2, varscan2
- TP53 | c.942del p.S315Lfs*30 | Frame Shift Del (DEL) | VAF 24/49 reads (49%) | catalogued as COSV99433274; called by mutect2, pindel, varscan2
- TRIM15 | c.4C>T p.P2S | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as rs1349084181, COSV64989736; called by muse, mutect2, varscan2
- TTC3 | c.5567C>G p.P1856R | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61291294, COSV61296404; called by muse, mutect2, varscan2
- TTN | c.28355A>G p.Y9452C (on ENST00000591111; = p.Y8525C on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 121/221 reads (55%) | PolyPhen probably damaging (0.999); catalogued as COSV60112694; called by muse, mutect2, varscan2
- USF3 | c.3251C>T p.A1084V | Missense Mutation (SNP) | VAF 45/151 reads (30%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.492); catalogued as rs1197315173, COSV57073923; called by muse, mutect2, varscan2
- VNN1 | c.28del p.A10Qfs*32 | Frame Shift Del (DEL) | VAF 6/22 reads (27%) | catalogued as COSV100907828, COSV63390869; called by mutect2, pindel, varscan2
- WWC3 | c.2168A>T p.H723L | Missense Mutation (SNP) | VAF 38/46 reads (83%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV66503991; called by muse, mutect2, varscan2
- XIRP2 | c.7841T>C p.I2614T (on ENST00000628543; = p.I2789T on NM_152381.6) | Missense Mutation (SNP) | VAF 39/90 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54706305; called by muse, mutect2, varscan2
- ZNF30 | c.1285G>T p.E429* | Nonsense Mutation (SNP) | VAF 52/94 reads (55%) | catalogued as COSV57854132; called by muse, mutect2, varscan2
- ZNF449 | c.729G>T p.E243D | Missense Mutation (SNP) | VAF 56/71 reads (79%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.755); catalogued as COSV59347244; called by muse, mutect2, varscan2
- CDC42BPB | c.627dup p.V210Rfs*9 | Frame Shift Ins (INS) | VAF 18/57 reads (32%) | called by mutect2, pindel, varscan2
- FRS3 | c.980del p.P327Hfs*64 | Frame Shift Del (DEL) | VAF 7/26 reads (27%) | called by mutect2, pindel, varscan2
- IGKV2D-24 | c.22C>A p.L8M | Missense Mutation (SNP) | VAF 13/23 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- IL12RB1 | c.700+1del p.X234_splice | Splice Site (DEL) | VAF 14/36 reads (39%) | called by mutect2, pindel, varscan2
- IMMT | c.2211dup p.V738Sfs*43 | Frame Shift Ins (INS) | VAF 8/70 reads (11%) | called by mutect2, varscan2
- NOS1AP | c.852_853del p.E284Dfs*40 | Frame Shift Del (DEL) | VAF 15/122 reads (12%) | called by pindel, varscan2
- THSD7B | c.1934dup p.S646* | Frame Shift Ins (INS) | VAF 20/58 reads (34%) | called by mutect2, pindel, varscan2
- TRAV2 | c.32G>A p.W11* | Nonsense Mutation (SNP) | VAF 39/74 reads (53%) | called by muse, mutect2, varscan2
- ALKBH3 | c.564G>A p.V188= | Silent (SNP) | VAF 31/81 reads (38%) | catalogued as COSV57024603; called by muse, mutect2, varscan2
- ALMS1 | c.11610A>C p.S3870= | Silent (SNP) | VAF 14/152 reads (9%) | catalogued as COSV52511742; called by muse, mutect2, varscan2
- DNAH11 | c.12040A>C p.R4014= | Silent (SNP) | VAF 18/46 reads (39%) | catalogued as COSV60959754; called by muse, mutect2, varscan2
- DSCAML1 | c.3240G>C p.R1080= (on ENST00000321322; = p.R1020= on NM_020693.4) | Silent (SNP) | VAF 10/56 reads (18%) | catalogued as COSV58392617; called by muse, mutect2, varscan2
- ELOA2 | c.864T>A p.A288= | Silent (SNP) | VAF 46/86 reads (53%) | catalogued as COSV55300788; called by muse, mutect2, varscan2
- GABRG1 | c.1185T>A p.S395= | Silent (SNP) | VAF 12/35 reads (34%) | catalogued as COSV54955265; called by muse, mutect2, varscan2
- KCNJ15 | c.1038T>C p.S346= | Silent (SNP) | VAF 21/55 reads (38%) | catalogued as COSV60811118; called by muse, mutect2, varscan2
- KCNN2 | c.1527C>A p.T509= (on ENST00000264773; = p.T721= on NM_021614.4) | Silent (SNP) | VAF 38/73 reads (52%) | catalogued as COSV53290184; called by muse, mutect2, varscan2
- KIF21A | c.1308T>A p.R436= | Silent (SNP) | VAF 14/170 reads (8%) | catalogued as rs1474014660, COSV62770148; called by muse, mutect2
- LPCAT4 | c.534A>T p.R178= | Silent (SNP) | VAF 45/136 reads (33%) | catalogued as COSV59217206; called by muse, mutect2, varscan2
- LRP1B | c.576T>A p.S192= | Silent (SNP) | VAF 17/58 reads (29%) | catalogued as COSV67230122; called by muse, mutect2, varscan2
- MED16 | c.1941G>T p.R647= | Silent (SNP) | VAF 6/15 reads (40%) | catalogued as COSV54127133; called by muse, mutect2, varscan2
- MVB12B | c.717G>A p.T239= | Silent (SNP) | VAF 35/108 reads (32%) | catalogued as rs760921172, COSV63258814; called by muse, mutect2, varscan2
- MYH4 | c.1758C>A p.A586= | Silent (SNP) | VAF 29/52 reads (56%) | catalogued as COSV55119516; called by muse, mutect2, varscan2
- NBEA | c.6309G>T p.T2103= | Silent (SNP) | VAF 31/53 reads (58%) | catalogued as COSV59757019, COSV59770428; called by muse, mutect2, varscan2
- NLRP10 | c.579T>C p.G193= | Silent (SNP) | VAF 9/25 reads (36%) | catalogued as COSV60780633; called by muse, mutect2, varscan2
- NRG3 | c.2082G>T p.L694= (on ENST00000404547 / NM_001370084.1; = p.L670= on NM_001010848.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 15/53 reads (28%) | catalogued as COSV64566547; called by muse, mutect2, varscan2
- OR2M2 | c.96G>C p.L32= | Silent (SNP) | VAF 76/144 reads (53%) | catalogued as COSV62898530; called by muse, mutect2, varscan2
- OR4S2 | c.507C>T p.P169= | Silent (SNP) | VAF 55/138 reads (40%) | catalogued as COSV56747170; called by muse, varscan2
- OR56B1 | c.561G>T p.L187= | Silent (SNP) | VAF 6/46 reads (13%) | catalogued as COSV57723256; called by muse, mutect2, varscan2
- PECAM1 | c.2193G>T p.T731= | Silent (SNP) | VAF 24/88 reads (27%) | called by muse, mutect2, varscan2
- PPARGC1A | c.2118C>T p.C706= | Silent (SNP) | VAF 39/65 reads (60%) | catalogued as COSV53528425; called by muse, mutect2, varscan2
- PTK2B | c.2850G>T p.L950= | Silent (SNP) | VAF 9/19 reads (47%) | catalogued as COSV53557960; called by muse, mutect2, varscan2
- RNASE1 | c.447T>C p.D149= | Silent (SNP) | VAF 41/66 reads (62%) | catalogued as COSV61754022; called by muse, mutect2, varscan2
- SNPH | c.120T>A p.S40= | Silent (SNP) | VAF 12/29 reads (41%) | catalogued as COSV67870822; called by muse, mutect2, varscan2
- SPATA31E1 | c.1287G>A p.G429= | Silent (SNP) | VAF 32/112 reads (29%) | catalogued as COSV57792455; called by muse, mutect2, varscan2
- TFG | c.315C>G p.L105= | Silent (SNP) | VAF 31/116 reads (27%) | catalogued as COSV53748655, COSV53749131; called by muse, mutect2, varscan2
- THG1L | c.294G>A p.V98= | Silent (SNP) | VAF 43/68 reads (63%) | catalogued as COSV51453026; called by muse, mutect2, varscan2
- TTN | c.101910A>G p.A33970= (on ENST00000591111; = p.A26546= on NM_003319.4) | Silent (SNP) | VAF 19/81 reads (23%) | catalogued as COSV60112644; called by muse, mutect2, varscan2
- URI1 | c.1596A>G p.Q532= | Silent (SNP) | VAF 25/95 reads (26%) | catalogued as COSV56350562; called by muse, mutect2, varscan2
- UTP15 | c.249A>G p.A83= | Silent (SNP) | VAF 38/57 reads (67%) | catalogued as rs374072213; called by muse, mutect2, varscan2
- ZC4H2 | c.624C>A p.A208= | Silent (SNP) | VAF 7/18 reads (39%) | catalogued as rs1416884513, COSV62004082; called by muse, mutect2, varscan2
- AL353804.7 | chrX:73849702 G>T | 5'Flank (SNP) | VAF 11/23 reads (48%) | called by muse, mutect2
- FAM183BP | n.1122G>T | RNA (SNP) | VAF 60/110 reads (55%) | called by muse, mutect2, varscan2
